Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A8BP, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A8BP-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

....

Clinical Diagnosis & History:

Right thigh sarcoma, core biopsy consistent with MFH.

Specimens Submitted:

1: SP: Right anterior thigh high grade sarcoma

DIAGNOSIS:

1. RIGHT ANTERIOR THIGH, RESECTION:

- HIGH GRADE MALIGNANT FIBROUS HISTIOCYTOMA, STORIFORM-PLEOMORPHIC TYPE.

- TUMOR SIZE: 12.3 x 8.2 x 6.6 CM.

- TUMOR INVOLVES SKELETAL MUSCLE

- THERE ARE AREAS OF NECROSIS AND A BRISK MITOTIC ACTIVITY (14 MF / 10

HPFs).

- TUMOR EXTENDS FOCALLY TO AN UNDESIGNATED INKED MARGIN.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

The specimen is received fresh, labeled "right anterior thigh, high grade sarcoma." It consists of an unoriented skeletal muscle measuring 17 x 14 x 6 cm. The specimen is inked entirely black and serially sectioned to reveal a white and yellow well-circumscribed soft tumor measuring 12.3 x 8.2 x 6.6 cm. The tumor grossly extends to within 1mm of the nearest margin is surrounded by a thin membrane. TPS is submitted. Gross photos are taken. Representative sections are submitted.

Summary of sections:

Tmtumor with margin

t-tumor

** Continued on next page **

ICD-O-3
Histiocytoma, fibrous malignant,
pleomorphic 8830/3
Site R Thigh NOS C49.2
Jt 5/11/22/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

[REDACTED]

[REDACTED]

Page 2 of 2

Summary of Sections:

Part 1: SP: Right anterior thigh high grade sarcoma

Block	Sect.	Site	PCs
6	t		6
2	tm		2

** End of Report **

Source: NCI Genomic Data Commons file 92b17241-8520-4f06-bedf-97d80234c55d (TCGA-DX-A8BP.CB49CC29-CC7B-4C60-806A-4B3D37074B56.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).